Somatic mutation profile of tumor specimen TCGA-BK-A4ZD-01A (aliquot TCGA-BK-A4ZD-01A-11D-A27P-09) from TCGA case TCGA-BK-A4ZD, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Endometrium; FIGO stage: Stage IA; Tumor grade: G3; Age at diagnosis: 42.5 years (15,536 days).
Specimen TCGA-BK-A4ZD-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 09cd82b6-a24d-4439-abd4-47ede79f97fd.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-BK-A4ZD-10A (Blood Derived Normal), aliquot TCGA-BK-A4ZD-10A-01D-A27P-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/aed050de-572e-4979-9e5b-0b4361b049d9

The open-access MAF lists 80 somatic variants for this specimen: 58 protein-altering or splice-affecting, 20 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 46, Silent 20, Nonsense Mutation 5, In Frame Del 2, Splice Site 2, Frame Shift Ins 1, Intron 1, RNA 1, Splice Region 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- F9 | c.835G>A p.A279T | Missense Mutation (SNP) | VAF 6/49 reads (12%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.571); catalogued as rs137852247, CM1314241, CM940587, COSV54378539; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- MYO7A | c.287C>T p.T96M | Missense Mutation (SNP) | VAF 32/47 reads (68%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs781811444, COSV68685635; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- PTEN | c.276C>A p.D92E | Missense Mutation (SNP) | VAF 10/64 reads (16%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs779530981, CM033666, COSV64288954, COSV64292660; called by muse, mutect2
- PTEN | c.723dup p.E242* | Frame Shift Ins (INS) | VAF 39/85 reads (46%) | catalogued as rs1060500115; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- TP53 | c.743G>A p.R248Q | Missense Mutation (SNP) | VAF 38/48 reads (79%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs11540652, CM920675, COSV52661091, COSV52661580, COSV52675468, COSV52802300; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ADGRB3 | c.1096A>T p.R366* | Nonsense Mutation (SNP) | VAF 28/166 reads (17%) | catalogued as COSV101002045, COSV65397061, COSV65406871; called by muse, mutect2, varscan2
- ADGRB3 | c.1199A>C p.D400A | Missense Mutation (SNP) | VAF 64/99 reads (65%) | SIFT deleterious (0); PolyPhen possibly damaging (0.549); catalogued as COSV101002046; called by muse, mutect2, varscan2
- ATAD2 | c.3193C>T p.P1065S | Missense Mutation (SNP) | VAF 10/144 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV99785461; called by muse, mutect2
- CDKN2C | c.217G>A p.V73I | Missense Mutation (SNP) | VAF 28/44 reads (64%) | SIFT tolerated (0.71); PolyPhen probably damaging (0.974); catalogued as COSV99396101; called by muse, mutect2, varscan2
- CHD8 | c.6130C>T p.R2044* (on ENST00000646647 / NM_001170629.2; = p.R1765* on NM_020920.4) | Nonsense Mutation (SNP) | VAF 24/60 reads (40%) | catalogued as rs772226664, COSV63036406; called by muse, mutect2, varscan2
- COL22A1 | c.3821C>G p.P1274R | Missense Mutation (SNP) | VAF 13/61 reads (21%) | SIFT tolerated (0.65); PolyPhen possibly damaging (0.511); catalogued as rs748557677, COSV100281204; called by muse, mutect2, varscan2
- CRYBA4 | c.212G>A p.R71Q | Missense Mutation (SNP) | VAF 16/52 reads (31%) | SIFT tolerated (0.11); PolyPhen benign (0.155); catalogued as rs778397499, COSV100697877; called by muse, mutect2
- CSMD3 | c.4793T>A p.F1598Y (on ENST00000297405 / NM_001363185.1; = p.F1494Y on NM_052900.3) | Missense Mutation (SNP) | VAF 9/50 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.916); catalogued as COSV99850874; called by muse, mutect2, varscan2
- DAB1 | c.1304A>G p.Q435R (on ENST00000371231; = p.Q402R on NM_021080.5 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 11/70 reads (16%) | SIFT tolerated (0.16); PolyPhen benign (0.41); catalogued as rs1347270520, COSV100976736; called by muse, mutect2, varscan2
- DAZL | c.500C>A p.A167E | Missense Mutation (SNP) | VAF 56/163 reads (34%) | SIFT deleterious (0.03); PolyPhen benign (0.309); catalogued as COSV99167556; called by muse, mutect2, varscan2
- DCAF1 | c.2519A>T p.Q840L | Missense Mutation (SNP) | VAF 11/30 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.24); catalogued as COSV100245049; called by muse, mutect2, varscan2
- DKC1 | c.211C>T p.P71S | Missense Mutation (SNP) | VAF 10/84 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.85); catalogued as COSV101059904; called by muse, mutect2, varscan2
- DOK2 | c.1181C>T p.S394F | Missense Mutation (SNP) | VAF 11/50 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.181); catalogued as COSV99375015; called by muse, mutect2, varscan2
- DOT1L | c.1334C>T p.A445V | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.307); catalogued as rs753115153, COSV67111775; called by muse, mutect2, varscan2
- DTX1 | c.1319G>A p.R440H | Missense Mutation (SNP) | VAF 10/40 reads (25%) | SIFT deleterious (0.03); PolyPhen benign (0.019); catalogued as rs753280687, COSV99922207; called by muse, mutect2, varscan2
- DYDC2 | c.515G>T p.G172V | Missense Mutation (SNP) | VAF 3/32 reads (9%) | SIFT deleterious (0.02); PolyPhen benign (0.36); catalogued as COSV99758229; called by muse, mutect2
- EFCAB3 | c.1055A>G p.N352S | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT tolerated (0.07); PolyPhen benign (0.097); catalogued as COSV100540555; called by muse, mutect2, varscan2
- EPHB6 | c.2774C>A p.T925N | Missense Mutation (SNP) | VAF 8/51 reads (16%) | SIFT tolerated (0.07); PolyPhen benign (0.272); catalogued as COSV100844487, COSV63890855; called by muse, mutect2, varscan2
- FAM122B | c.276G>C p.L92= | Splice Region (SNP) | VAF 5/29 reads (17%) | catalogued as COSV99980553; called by muse, mutect2, varscan2
- FAM163A | c.449C>T p.P150L | Missense Mutation (SNP) | VAF 12/36 reads (33%) | SIFT tolerated (0.62); PolyPhen benign (0.368); catalogued as COSV100523213; called by muse, mutect2, varscan2
- FFAR4 | c.796A>G p.S266G | Missense Mutation (SNP) | VAF 16/55 reads (29%) | SIFT tolerated (0.13); PolyPhen benign (0.061); catalogued as COSV101012308; called by muse, mutect2, varscan2
- GALNTL6 | c.377G>A p.R126H | Missense Mutation (SNP) | VAF 7/27 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV101487914; called by muse, mutect2, varscan2
- GCM2 | c.412G>A p.V138I | Missense Mutation (SNP) | VAF 16/35 reads (46%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as rs775445560, COSV65275712; called by muse, varscan2
- GPATCH8 | c.568G>T p.E190* | Nonsense Mutation (SNP) | VAF 7/25 reads (28%) | catalogued as COSV100132926; called by muse, mutect2, varscan2
- GPT | c.55A>G p.K19E | Missense Mutation (SNP) | VAF 14/60 reads (23%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.703); catalogued as COSV99477901; called by muse, mutect2, varscan2
- GRIPAP1 | c.1179G>T p.E393D | Missense Mutation (SNP) | VAF 9/40 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.89); catalogued as COSV100904422; called by muse, mutect2, varscan2
- INPP5D | c.1789T>A p.W597R (on ENST00000445964 / NM_001017915.3; = p.W596R on NM_005541.5) | Missense Mutation (SNP) | VAF 11/87 reads (13%) | SIFT tolerated (0.1); PolyPhen benign (0.295); catalogued as COSV100857004; called by muse, mutect2, varscan2
- IQSEC3 | c.72C>G p.N24K | Missense Mutation (SNP) | VAF 4/9 reads (44%) | SIFT deleterious (0); PolyPhen benign (0.413); catalogued as rs2650190, COSV58280056; called by mutect2, varscan2
- KIT | c.71C>T p.S24F | Missense Mutation (SNP) | VAF 7/39 reads (18%) | SIFT tolerated (0.7); PolyPhen benign (0.035); catalogued as COSV55420257; called by muse, mutect2, varscan2
- LAS1L | c.847G>T p.V283L | Missense Mutation (SNP) | VAF 3/22 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.832); catalogued as COSV100408722; called by muse, mutect2
- ME3 | c.865C>T p.R289C | Missense Mutation (SNP) | VAF 47/73 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as rs1168887658, COSV100042563; called by muse, mutect2, varscan2
- MET | c.2359A>G p.T787A | Missense Mutation (SNP) | VAF 10/51 reads (20%) | SIFT tolerated (0.4); PolyPhen possibly damaging (0.589); catalogued as rs1180556775, COSV59268543; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MPO | c.41A>C p.D14A | Missense Mutation (SNP) | VAF 18/20 reads (90%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0); catalogued as COSV99833104; called by muse, mutect2, varscan2
- MS4A14 | c.1013A>C p.K338T | Missense Mutation (SNP) | VAF 5/31 reads (16%) | SIFT tolerated (0.48); PolyPhen benign (0); catalogued as rs1488946974, COSV100280777; called by muse, mutect2, varscan2
- NSF | c.1747C>T p.Q583* | Nonsense Mutation (SNP) | VAF 19/45 reads (42%) | catalogued as COSV99834076; called by muse, mutect2, varscan2
- OR5M10 | c.106C>G p.L36V | Missense Mutation (SNP) | VAF 6/72 reads (8%) | SIFT tolerated (0.13); PolyPhen benign (0.011); catalogued as COSV101595932; called by muse, mutect2
- PAK3 | c.67C>G p.R23G | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT tolerated (0.24); PolyPhen benign (0); catalogued as COSV53272582, COSV53276222, COSV99458522; called by muse, mutect2, varscan2
- PZP | c.2207C>T p.T736M | Missense Mutation (SNP) | VAF 14/38 reads (37%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.908); catalogued as rs200058002; called by muse, mutect2, varscan2
- SATB1 | c.1201A>T p.T401S | Missense Mutation (SNP) | VAF 17/45 reads (38%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.972); catalogued as COSV100113522; called by muse, mutect2, varscan2
- SLC22A6 | c.535G>A p.A179T | Missense Mutation (SNP) | VAF 7/56 reads (13%) | SIFT tolerated (0.96); PolyPhen benign (0.015); catalogued as rs766145348, COSV64559813; called by muse, mutect2, varscan2
- SLC4A4 | c.1208+1G>T p.X403_splice (on ENST00000264485 / NM_001098484.3; = p.X359_splice on NM_003759.4) | Splice Site (SNP) | VAF 4/62 reads (6%) | catalogued as COSV99143273; called by muse, mutect2
- SNRPN | c.174A>C p.Q58H | Missense Mutation (SNP) | VAF 17/39 reads (44%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.969); catalogued as COSV100578735; called by muse, mutect2, varscan2
- SPHKAP | c.4828G>A p.V1610M (on ENST00000392056 / NM_001142644.2; = p.V1581M on NM_030623.3) | Missense Mutation (SNP) | VAF 8/51 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100764623; called by muse, mutect2, varscan2
- TAF1L | c.857G>A p.R286H | Missense Mutation (SNP) | VAF 41/68 reads (60%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as rs377436325; called by muse, mutect2, varscan2
- TP73 | c.1736G>A p.R579H | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.998); catalogued as rs376429700, COSV60706684; called by muse, mutect2
- TPTE2 | c.500G>A p.R167K | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as COSV99691204; called by muse, mutect2, varscan2
- ZC3H4 | c.3794C>T p.T1265M | Missense Mutation (SNP) | VAF 17/53 reads (32%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.8); catalogued as rs766266343, COSV99452954; called by muse, mutect2, varscan2
- ZNF514 | c.260G>A p.W87* | Nonsense Mutation (SNP) | VAF 17/61 reads (28%) | catalogued as COSV99728069; called by muse, mutect2, varscan2
- ZNF781 | c.800C>A p.T267K | Missense Mutation (SNP) | VAF 8/46 reads (17%) | SIFT tolerated (0.92); PolyPhen benign (0.006); catalogued as COSV100669438; called by muse, mutect2, varscan2
- CGB7 | c.184-1G>C p.X62_splice | Splice Site (SNP) | VAF 5/24 reads (21%) | called by mutect2, varscan2
- DNASE1 | c.481_484delinsA p.D161_A162delinsT | In Frame Del (DEL) | VAF 25/41 reads (61%) | called by pindel, varscan2*
- EMC1 | c.2333_2338del p.A778_K779del | In Frame Del (DEL) | VAF 38/67 reads (57%) | called by mutect2, pindel, varscan2
- FAM3A | c.209del p.L70Rfs*24 | Frame Shift Del (DEL) | VAF 24/60 reads (40%) | called by mutect2, pindel, varscan2
- ABHD17A | c.693C>T p.F231= (on ENST00000292577 / NM_001130111.2; = p.F282= on NM_031213.4) | Silent (SNP) | VAF 6/16 reads (38%) | catalogued as rs750526442, COSV99171367; called by muse, mutect2, varscan2
- ADGRB3 | c.2403G>A p.S801= | Silent (SNP) | VAF 21/69 reads (30%) | catalogued as rs773510249, COSV65390306; called by muse, mutect2, varscan2
- EZHIP | c.1005C>G p.R335= | Silent (SNP) | VAF 21/57 reads (37%) | catalogued as COSV100539958; called by muse, mutect2, varscan2
- GPA33 | c.564C>A p.A188= | Silent (SNP) | VAF 17/75 reads (23%) | catalogued as rs376202132; called by muse, mutect2, varscan2
- GRIK3 | c.393C>G p.P131= | Silent (SNP) | VAF 23/96 reads (24%) | catalogued as COSV100902420, COSV66136621; called by muse, mutect2, varscan2
- IGKV1D-12 | c.66C>T p.C22= | Silent (SNP) | VAF 14/87 reads (16%) | catalogued as rs201178352; called by muse, mutect2, varscan2
- JADE3 | c.63T>C p.F21= | Silent (SNP) | VAF 7/32 reads (22%) | catalogued as COSV99510438; called by muse, mutect2, varscan2
- KLHL1 | c.72C>T p.H24= | Silent (SNP) | VAF 12/42 reads (29%) | catalogued as COSV100918196, COSV100918332, COSV64772371; called by muse, mutect2, varscan2
- KMT2E | c.2586T>C p.C862= | Silent (SNP) | VAF 9/27 reads (33%) | catalogued as COSV99997168; called by muse, mutect2, varscan2
- LRRC8E | c.747C>T p.D249= | Silent (SNP) | VAF 7/51 reads (14%) | catalogued as rs187420783, COSV100143174; called by muse, mutect2, varscan2
- MIS18BP1 | c.2277T>C p.A759= | Silent (SNP) | VAF 14/77 reads (18%) | catalogued as COSV100173332; called by muse, mutect2, varscan2
- PCDH10 | c.246A>G p.E82= | Silent (SNP) | VAF 6/16 reads (38%) | catalogued as COSV99994728; called by muse, mutect2, varscan2
- PCDHA12 | c.2004G>A p.S668= | Silent (SNP) | VAF 30/66 reads (45%) | catalogued as COSV56540990; called by muse, mutect2, varscan2
- PPAN-P2RY11 | c.1452C>A p.A484= | Silent (SNP) | VAF 15/36 reads (42%) | catalogued as COSV53455936, COSV99461942; called by muse, mutect2, varscan2
- PPFIA3 | c.2127C>T p.A709= | Silent (SNP) | VAF 14/43 reads (33%) | catalogued as COSV100495377; called by muse, mutect2, varscan2
- SLC38A3 | c.1149C>T p.I383= | Silent (SNP) | VAF 14/39 reads (36%) | catalogued as rs587721992, COSV68844190; called by muse, mutect2, varscan2
- SORCS3 | c.2418G>A p.R806= | Silent (SNP) | VAF 11/45 reads (24%) | catalogued as COSV100863916, COSV63799516; called by muse, mutect2, varscan2
- TFAP2D | c.264C>T p.D88= | Silent (SNP) | VAF 14/65 reads (22%) | catalogued as COSV50408497; called by muse, mutect2, varscan2
- VPS13C | c.4998A>G p.G1666= (on ENST00000644861 / NM_020821.3; = p.G1623= on NM_017684.5) | Silent (SNP) | VAF 13/35 reads (37%) | catalogued as COSV99830572; called by muse, mutect2, varscan2
- YAF2 | c.542A>G p.*181= | Silent (SNP) | VAF 7/27 reads (26%) | catalogued as rs1201495775, COSV100586503; called by muse, mutect2, varscan2
- CIT | c.4729-453C>G | Intron (SNP) | VAF 5/33 reads (15%) | catalogued as rs372358981; called by muse, mutect2, varscan2
- SNORD114-16 | n.10T>G | RNA (SNP) | VAF 5/31 reads (16%) | called by muse, mutect2, varscan2
